Gene-level copy-number profile of tumor specimen ALCH-B2UE-TTP1-A from ALCHEMIST case ALCH-B2UE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.2 years (30,030 days).
Specimen ALCH-B2UE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c6a254f-29b6-4d12-8f1d-889309ea3ab2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/1a0a0c63-a798-4d7f-8168-fee614f52c57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3,269; copy number 2: 49,611; copy number 3: 5,902; copy number 4: 79; copy number 5: 1; copy number 6: 2; copy number 7: 4; copy number 8: 2; copy number 9: 1; copy number 13: 6; copy number 14: 1; copy number 15: 1; copy number 21: 1; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.
- chr11:17,493,895–17,544,416, 1 gene: USH1C.
- chr11:76,190,725–76,195,071, 1 gene (within-gene range 0–1): AP000785.1.
- chr14:105,639,559–105,644,790, 1 gene (within-gene range 0–7): IGHG2.
- chr14:105,647,924–105,649,057, 1 gene: COPDA1.
- chr15:25,232,387–25,257,027, 12 genes (within-gene range 0–1): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr21:43,358,147–43,362,349, 1 gene: LINC01679.
- chr21:43,414,483–43,453,902, 2 genes: SIK1, LINC00319.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–14): AP001048.1.
- chr21:43,551,229–43,551,600, 1 gene (within-gene range 0–3): RPL31P1.
- chr22:41,229,510–41,286,187, 3 genes (within-gene range 0–1): CHADL, RANGAP1, MIR6889.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 7: AC113430.1.
- chr11:1,688,297–1,689,056, 1 gene, copy number 21: LINC02708.
- chr11:1,734,821–1,764,573, 2 genes, copy number 7 (within-gene range 1–7): AC068580.4, CTSD.
- chr11:1,776,930–1,778,388, 1 gene, copy number 15: AC068580.2.
- chr11:1,983,237–2,001,470, 6 genes, copy number 13 (within-gene range 3–13): MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr12:132,169,823–132,170,043, 1 gene, copy number 27: AC138466.3.
- chr14:105,620,506–105,626,066, 1 gene, copy number 5 (within-gene range 3–5): IGHG4.
- chr14:105,640,168–105,640,232, 1 gene, copy number 7: MIR8071-2.
- chr19:1,238,179–1,244,825, 2 genes, copy number 6: AC004221.1, ATP5F1D.
- chr19:1,259,384–1,279,244, 3 genes, copy number 8–9: CIRBP, CIRBP-AS1, FAM174C.
- chr21:43,461,960–43,479,534, 1 gene, copy number 14 (within-gene range 0–14): LINC00313.

Autosomal genes at a single copy (total copy number 1): 413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
